Somatic mutation profile of tumor specimen ALCH-B4B9-TTP1-A (aliquot ALCH-B4B9-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4B9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.5 years (26,112 days).
Specimen ALCH-B4B9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02378a7e-bc13-451f-84fe-cb35e2fe992e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4B9-NB1-A (Blood Derived Normal), aliquot ALCH-B4B9-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88240f47-ea58-46db-be55-6ba2bef32c0d

The open-access MAF lists 339 somatic variants for this specimen: 226 protein-altering or splice-affecting, 73 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 73, Intron 18, Nonsense Mutation 14, RNA 9, 5'UTR 8, Frame Shift Del 6, 5'Flank 3, In Frame Del 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMB2 | c.4762C>T p.Q1588* | Nonsense Mutation (SNP) | VAF 167/566 reads (30%) | catalogued as rs775456607; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SGCB | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as rs752492870, CM971347, CM971348; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 238/738 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs974595753; called by muse, mutect2, varscan2
- ANHX | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as rs761707831; called by muse, mutect2, varscan2
- ANK1 | c.5233G>A p.G1745S | Missense Mutation (SNP) | VAF 80/943 reads (8%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs765493524; called by muse, mutect2
- ASPM | c.4720C>A p.Q1574K | Missense Mutation (SNP) | VAF 137/668 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.349); catalogued as rs776034810; called by muse, mutect2, varscan2
- ASPM | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 108/895 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54128917; called by muse, mutect2, varscan2
- ATP2A1 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 146/685 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1318387122, COSV100707136, COSV62869441; called by muse, mutect2, varscan2
- BEND3 | c.2260G>A p.A754T | Missense Mutation (SNP) | VAF 144/374 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs150257161, COSV64681132; called by muse, mutect2, varscan2
- BHLHA15 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 132/416 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs369434835; called by muse, mutect2, varscan2
- C3 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 340/1266 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.035); catalogued as rs199784156, COSV99837128; called by muse, mutect2, varscan2
- CACNA1B | c.4352G>A p.R1451Q | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1289601418, COSV53111739, COSV99499705; called by muse, mutect2, varscan2
- CD1E | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.147); catalogued as rs1193898957, COSV100936999; called by muse, mutect2, varscan2
- CDKN2A | c.212A>T p.N71I | Missense Mutation (SNP) | VAF 217/617 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM112063, CM940228, CM983987, COSV58705792; called by muse, mutect2, varscan2
- CFAP54 | c.4552C>T p.R1518* | Nonsense Mutation (SNP) | VAF 35/630 reads (6%) | catalogued as rs1043155735, COSV61571920; called by muse, mutect2
- CSMD3 | c.11055C>A p.N3685K (on ENST00000297405 / NM_001363185.1; = p.N3516K on NM_052900.3) | Missense Mutation (SNP) | VAF 235/1037 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV52132235, COSV52260743; called by muse, mutect2, varscan2
- DACT1 | c.643G>C p.G215R | Missense Mutation (SNP) | VAF 87/624 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV60023217; called by muse, mutect2, varscan2
- DCSTAMP | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 248/1184 reads (21%) | catalogued as rs200311973, COSV52576874; called by muse, mutect2, varscan2
- DGKI | c.295G>T p.G99W | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); catalogued as rs1453450596; called by muse, mutect2, varscan2
- EXOC3L4 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.371); catalogued as rs775808393, COSV66295457; called by muse, mutect2, varscan2
- FADD | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 2570/3042 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99042419; called by muse, mutect2, varscan2
- FGF10 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 201/1345 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV52940140; called by muse, mutect2, varscan2
- FSCB | c.2293G>T p.V765L | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100469212; called by muse, mutect2, varscan2
- GALC | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 132/666 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV54322791; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1249_1251del p.E417del | In Frame Del (DEL) | VAF 92/814 reads (11%) | catalogued as rs1282315169; called by mutect2, varscan2
- GRWD1 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs146895668; called by muse, mutect2, varscan2
- GTF3C4 | c.1692G>C p.K564N | Missense Mutation (SNP) | VAF 152/786 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV100936091; called by muse, mutect2, varscan2
- H2AC4 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 164/559 reads (29%) | catalogued as COSV52518859; called by muse, mutect2, varscan2
- IGHV1-18 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 199/757 reads (26%) | catalogued as rs377167671; called by muse, mutect2, varscan2
- IKBKB | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 83/641 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201303042; called by muse, mutect2, varscan2
- KBTBD13 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs952061379; called by muse, mutect2, varscan2
- KCNAB1 | c.284G>C p.G95A (on ENST00000490337 / NM_172160.3; = p.G84A on NM_003471.3) | Missense Mutation (SNP) | VAF 62/370 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56746915; called by muse, mutect2, varscan2
- KCNE2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 163/423 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411888390, COSV51710492; called by muse, mutect2, varscan2
- KCNH2 | c.1632G>T p.E544D | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CD001500; called by muse, mutect2, varscan2
- KCNIP1 | c.420del p.W140* (on ENST00000411494 / NM_001034837.3; = p.W129* on NM_014592.4) | Frame Shift Del (DEL) | VAF 142/503 reads (28%) | catalogued as COSV100200106; called by mutect2, pindel, varscan2
- KCNK9 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.07); catalogued as rs574923557; called by muse, mutect2, varscan2
- KDR | c.2213A>G p.Q738R | Missense Mutation (SNP) | VAF 246/1193 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs779599662; called by muse, mutect2, varscan2
- KIF7 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101067835; called by muse, mutect2, varscan2
- LMNA | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 162/666 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs747139279, COSV61544015; called by muse, mutect2, varscan2
- MAGEC3 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs1228298123; called by muse, mutect2, varscan2
- MAN2B2 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 50/499 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs750207824, COSV53456161; called by muse, mutect2, varscan2
- MAP10 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs780194188; called by muse, mutect2, varscan2
- MTCL1 | c.1138C>T p.R380W (on ENST00000306329 / NM_001378206.1; = p.R20W on NM_015210.4) | Missense Mutation (SNP) | VAF 345/1141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60406272; called by muse, mutect2, varscan2
- MUC2 | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs771572893; called by muse, mutect2, varscan2
- MYH11 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 119/1112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748165862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH3 | c.4720G>C p.D1574H | Missense Mutation (SNP) | VAF 126/411 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56869129; called by muse, mutect2, varscan2
- NEGR1 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 62/560 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100160092, COSV60832075; called by muse, mutect2, varscan2
- NISCH | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 98/421 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100617288, COSV61899772; called by muse, mutect2, varscan2
- NKX6-1 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 50/880 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV99880193; called by muse, mutect2
- OR2AK2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV63547780; called by muse, mutect2, varscan2
- OR4L1 | c.419T>A p.L140Q | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV59850623; called by muse, mutect2, varscan2
- OR5D13 | c.366T>A p.Y122* | Nonsense Mutation (SNP) | VAF 123/435 reads (28%) | catalogued as COSV100686766; called by muse, mutect2, varscan2
- PAPLN | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53719361; called by muse, mutect2, varscan2
- PAPPA | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 156/539 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs570712795, COSV60280087; called by muse, mutect2, varscan2
- PCDHB2 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 134/406 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs201070541, COSV50579315, COSV99165043; called by muse, mutect2, varscan2
- PKD1 | c.809C>G p.P270R | Missense Mutation (SNP) | VAF 125/285 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs767853116; called by muse, mutect2, varscan2
- PKD1L3 | c.4493G>T p.G1498V | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV100626313; called by muse, mutect2, varscan2
- PRDM9 | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 125/744 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV57015064; called by muse, mutect2, varscan2
- PREX2 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 92/561 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs955096765; called by muse, mutect2, varscan2
- RFPL4B | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1251412630; called by muse, mutect2, varscan2
- RUNX1T1 | c.797G>A p.R266Q (on ENST00000265814 / NM_001198628.1; = p.R239Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/890 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359364143, COSV99750353; called by muse, mutect2, varscan2
- RYR3 | c.4886A>G p.Y1629C | Missense Mutation (SNP) | VAF 201/606 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV66779934; called by muse, mutect2, varscan2
- SAMD9 | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 187/713 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs368696956; called by muse, mutect2, varscan2
- SCYL3 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 120/523 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884262; called by muse, mutect2, varscan2
- SEC31B | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 61/569 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs768192279; called by muse, mutect2, varscan2
- SFRP4 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs780669813; called by muse, mutect2, varscan2
- SHC2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 46/500 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs371710895; called by muse, mutect2
- SLC14A2 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 182/425 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV54907449, COSV99676309; called by muse, mutect2, varscan2
- SPEG | c.7474C>T p.R2492C | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs939871492; called by muse, mutect2
- STK31 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 57/622 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs150391003; called by muse, mutect2
- STYXL2 | c.2108C>A p.P703H | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99609893; called by muse, mutect2, varscan2
- TBR1 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 61/563 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV101271490; called by muse, mutect2, varscan2
- TGIF2LX | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 215/600 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99383592; called by muse, mutect2, varscan2
- TMEM132D | c.91C>G p.R31G | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70596239, COSV70604577; called by muse, mutect2, varscan2
- TMEM244 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 84/1136 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs367909541; called by muse, mutect2
- TPSB2 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs745819060; called by mutect2, varscan2
- UNC13A | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 81/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs950847565, COSV53195450; called by muse, mutect2, varscan2
- VPS28 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 94/512 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as rs782576648; called by muse, mutect2, varscan2
- VWDE | c.3394G>T p.D1132Y | Missense Mutation (SNP) | VAF 201/1003 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV51721823; called by muse, mutect2, varscan2
- YIPF7 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 41/189 reads (22%) | catalogued as COSV100274715; called by muse, mutect2, varscan2
- ZFHX4 | c.7379G>C p.G2460A | Missense Mutation (SNP) | VAF 239/1044 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.225); catalogued as rs1296394293, COSV99268089; called by muse, mutect2, varscan2
- ZNF319 | c.1589A>G p.N530S | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.266); catalogued as rs748094738; called by muse, mutect2, varscan2
- ZNF804B | c.677A>T p.K226I | Missense Mutation (SNP) | VAF 99/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147649508; called by muse, mutect2, varscan2
- ZNF835 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 103/400 reads (26%) | catalogued as rs1384937116; called by muse, mutect2, varscan2
- ADAMTS19 | c.2267A>G p.Y756C | Missense Mutation (SNP) | VAF 191/697 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ADCY5 | c.2642T>C p.V881A | Missense Mutation (SNP) | VAF 149/716 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL2 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 155/1315 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOB | c.5813T>A p.L1938Q | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP10D | c.1364T>G p.V455G | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ATP13A5 | c.439_440delinsA p.R147Sfs*8 | Frame Shift Del (DEL) | VAF 97/903 reads (11%) | called by pindel, varscan2*
- ATP8A2 | c.2144T>C p.I715T | Missense Mutation (SNP) | VAF 127/376 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATXN7L1 | c.2028G>C p.K676N | Missense Mutation (SNP) | VAF 53/543 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BRINP3 | c.590A>T p.H197L | Missense Mutation (SNP) | VAF 90/651 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BRWD1 | c.1439A>G p.D480G | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf56 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 105/371 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CENPE | c.6917G>C p.R2306T | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CHFR | c.667G>C p.A223P (on ENST00000432561 / NM_001161345.1; = p.A182P on NM_018223.2) | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CHRNB1 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 183/719 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CLCNKA | c.1181C>A p.P394Q | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNDP2 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 230/451 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CNTN1 | c.1583C>A p.A528E | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CNTNAP4 | c.2668del p.L890Ffs*6 | Frame Shift Del (DEL) | VAF 92/898 reads (10%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.3406A>G p.S1136G | Missense Mutation (SNP) | VAF 66/566 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CRNN | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 88/682 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CSAG1 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 348/790 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- CSMD2 | c.1399C>G p.Q467E | Missense Mutation (SNP) | VAF 147/588 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CTHRC1 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 146/743 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYTH1 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 158/563 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DCAF12L2 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DGKI | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2
- DNMT3L | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 189/524 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- EEF2 | c.1052T>C p.L351S | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- EIF4G3 | c.2686A>T p.I896F | Missense Mutation (SNP) | VAF 199/704 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERBB4 | c.370A>G p.R124G | Missense Mutation (SNP) | VAF 201/496 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ERICH3 | c.2485del p.R829Gfs*7 | Frame Shift Del (DEL) | VAF 22/186 reads (12%) | called by mutect2, pindel, varscan2
- ERMARD | c.1654G>T p.V552F | Missense Mutation (SNP) | VAF 141/1265 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC4 | c.1995G>T p.R665S | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FADS1 | c.555C>A p.N185K | Missense Mutation (SNP) | VAF 99/733 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FBN2 | c.6818G>A p.G2273E | Missense Mutation (SNP) | VAF 196/713 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.2552G>A p.G851E | Missense Mutation (SNP) | VAF 119/986 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FMO3 | c.1585C>G p.L529V | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.159); called by muse, mutect2
- FNDC3B | c.151A>T p.I51L | Missense Mutation (SNP) | VAF 162/971 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FOSL2 | c.4T>C p.Y2H | Missense Mutation (SNP) | VAF 149/801 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GABRA4 | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 48/300 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GAD2 | c.1422T>A p.C474* | Nonsense Mutation (SNP) | VAF 94/471 reads (20%) | called by muse, mutect2, varscan2
- GIMAP6 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 329/1102 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GJC2 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 216/938 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPAT4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GRIK5 | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN2D | c.3089C>T p.P1030L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- GRM7 | c.2390C>T p.T797I | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HMGXB4 | c.1570G>A p.V524I | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- HNRNPLL | c.1217T>A p.V406E | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); called by muse, mutect2
- HOXC12 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- HOXD13 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 215/623 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HRC | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 58/306 reads (19%) | called by muse, varscan2
- IGLJ7 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 113/464 reads (24%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.1313A>C p.H438P | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KCNA5 | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 102/502 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF2B | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 112/994 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LAMA5 | c.6053G>C p.G2018A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- LMTK3 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPXN | c.534T>A p.C178* | Nonsense Mutation (SNP) | VAF 98/420 reads (23%) | called by muse, mutect2, varscan2
- LRRC53 | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 26/632 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- LRRC58 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 199/742 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MAP1A | c.5030A>C p.E1677A | Missense Mutation (SNP) | VAF 62/572 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MCF2 | c.1893del p.V632Cfs*11 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, varscan2
- MFAP3 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 138/469 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPS15 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MTSS1 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 178/719 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MYO9A | c.2423A>T p.Q808L | Missense Mutation (SNP) | VAF 171/549 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NIPBL | c.6326G>A p.C2109Y | Missense Mutation (SNP) | VAF 64/1018 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- NPHS1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 136/701 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OBSCN | c.11701G>A p.A3901T | Missense Mutation (SNP) | VAF 105/703 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10Q1 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR2C1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2T10 | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 78/698 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- OR8H1 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PAPPA2 | c.1159A>T p.S387C | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PCDHB2 | c.2355C>A p.S785R | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCM1 | c.5158G>C p.E1720Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, varscan2
- PDHX | c.942A>C p.K314N | Missense Mutation (SNP) | VAF 163/578 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDZRN4 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX3 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 346/988 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PGAP6 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 130/356 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG7 | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 133/502 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PMFBP1 | c.1127C>T p.T376I | Missense Mutation (SNP) | VAF 82/482 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- POC1B | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 111/352 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PPM1D | c.1378A>T p.N460Y | Missense Mutation (SNP) | VAF 101/429 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PREB | c.749G>T p.C250F | Missense Mutation (SNP) | VAF 157/389 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRPH | c.954G>C p.Q318H | Missense Mutation (SNP) | VAF 204/695 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PRR16 | c.836G>T p.R279I (on ENST00000407149 / NM_001300783.2; = p.R256I on NM_016644.2) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, varscan2
- PTPRT | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2
- PXDN | c.1796C>T p.T599I | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- QDPR | c.664_673del p.P222Efs*3 | Frame Shift Del (DEL) | VAF 149/937 reads (16%) | called by mutect2, pindel, varscan2
- RAB23 | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 256/677 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RAPGEF2 | c.2059C>G p.L687V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, varscan2
- RASEF | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 131/705 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- RELCH | c.3560G>A p.S1187N | Missense Mutation (SNP) | VAF 48/568 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2
- RIC8B | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 91/480 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- RICTOR | c.3676A>G p.T1226A | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SAMD4A | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SETX | c.6617G>C p.G2206A | Missense Mutation (SNP) | VAF 326/1162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.4781A>G p.Y1594C | Missense Mutation (SNP) | VAF 291/1224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.1307C>A p.A436D | Missense Mutation (SNP) | VAF 156/1146 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SIDT2 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 143/516 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A4 | c.1283G>C p.G428A | Missense Mutation (SNP) | VAF 81/416 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A6 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SLITRK6 | c.2222A>T p.N741I | Missense Mutation (SNP) | VAF 148/573 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SNAP91 | c.2392A>T p.K798* | Nonsense Mutation (SNP) | VAF 92/865 reads (11%) | called by muse, mutect2, varscan2
- SPACA1 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 108/353 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SPPL3 | c.1132A>T p.S378C | Missense Mutation (SNP) | VAF 70/470 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SPTA1 | c.2949G>T p.M983I | Missense Mutation (SNP) | VAF 95/798 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTAN1 | c.5723T>C p.L1908S | Missense Mutation (SNP) | VAF 304/1185 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STAT2 | c.1627A>G p.K543E | Missense Mutation (SNP) | VAF 75/533 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SV2C | c.978T>G p.C326W | Missense Mutation (SNP) | VAF 129/495 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D15 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCF3 | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TMEM161B | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TMEM64 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 81/714 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TP53 | c.428_436del p.V143_W146delinsG | In Frame Del (DEL) | VAF 94/341 reads (28%) | called by mutect2, pindel, varscan2
- TPH2 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 228/819 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIM60 | c.1223C>A p.P408Q | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TTN | c.64675A>C p.K21559Q (on ENST00000591111; = p.K14135Q on NM_003319.4) | Missense Mutation (SNP) | VAF 493/1357 reads (36%) | PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- UBTFL1 | c.39A>T p.K13N | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by mutect2, varscan2
- UGT2B11 | c.1453T>A p.W485R | Missense Mutation (SNP) | VAF 570/1671 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UHRF1BP1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.5458C>A p.L1820I | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- UNC80 | c.1338C>A p.F446L | Missense Mutation (SNP) | VAF 139/402 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- USF3 | c.3202C>A p.L1068I | Missense Mutation (SNP) | VAF 61/533 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USP29 | c.2507C>G p.P836R | Missense Mutation (SNP) | VAF 59/452 reads (13%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- USP46 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 136/568 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- USP9Y | c.1898G>C p.G633A | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- WNK3 | c.64T>A p.F22I | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT2 | c.906C>A p.D302E | Missense Mutation (SNP) | VAF 178/632 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZDHHC20 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 114/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZFHX4 | c.7703C>A p.T2568N | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZIM3 | c.840G>T p.Q280H | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF425 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 72/728 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF438 | c.2368G>T p.D790Y | Missense Mutation (SNP) | VAF 186/1016 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ZNF442 | c.1730G>T p.C577F | Missense Mutation (SNP) | VAF 159/542 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF496 | c.164G>C p.G55A | Missense Mutation (SNP) | VAF 124/465 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF585B | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF835 | c.1379A>G p.Y460C | Missense Mutation (SNP) | VAF 148/749 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZNF883 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 74/536 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNHIT6 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ABCA7 | c.1164C>T p.D388= | Silent (SNP) | VAF 98/460 reads (21%) | catalogued as rs754600576, COSV54027468; called by muse, mutect2, varscan2
- ACSM6 | c.945T>C p.S315= | Silent (SNP) | VAF 210/626 reads (34%) | called by muse, mutect2, varscan2
- ADARB2 | c.1617G>A p.Q539= | Silent (SNP) | VAF 132/674 reads (20%) | catalogued as COSV101186619; called by muse, mutect2, varscan2
- ADGRV1 | c.4557A>G p.G1519= | Silent (SNP) | VAF 157/483 reads (33%) | called by muse, mutect2, varscan2
- AFMID | c.39T>A p.V13= | Silent (SNP) | VAF 52/566 reads (9%) | called by muse, mutect2
- ANKRD33B | c.783C>A p.P261= | Silent (SNP) | VAF 352/843 reads (42%) | called by muse, mutect2, varscan2
- APOB | c.4431G>A p.Q1477= | Silent (SNP) | VAF 80/330 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF33 | c.1299T>C p.F433= | Silent (SNP) | VAF 68/830 reads (8%) | called by muse, mutect2
- C1orf56 | c.168T>A p.L56= | Silent (SNP) | VAF 97/356 reads (27%) | called by muse, varscan2
- C3 | c.3024G>A p.S1008= | Silent (SNP) | VAF 73/420 reads (17%) | catalogued as rs779366181, COSV55580545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACTIN | c.1137G>A p.K379= | Silent (SNP) | VAF 75/372 reads (20%) | called by muse, mutect2, varscan2
- CD1C | c.93C>T p.I31= | Silent (SNP) | VAF 39/404 reads (10%) | catalogued as COSV63806091; called by muse, mutect2
- CHST13 | c.759C>A p.L253= | Silent (SNP) | VAF 80/333 reads (24%) | called by muse, mutect2, varscan2
- CYP7A1 | c.723C>T p.S241= | Silent (SNP) | VAF 278/1305 reads (21%) | called by muse, mutect2, varscan2
- DUXA | c.237G>A p.E79= | Silent (SNP) | VAF 129/597 reads (22%) | called by muse, mutect2, varscan2
- EDN1 | c.426T>C p.H142= | Silent (SNP) | VAF 224/577 reads (39%) | called by muse, mutect2, varscan2
- FKTN | c.441A>G p.L147= | Silent (SNP) | VAF 259/1082 reads (24%) | called by muse, mutect2, varscan2
- FTMT | c.45G>C p.S15= | Silent (SNP) | VAF 103/367 reads (28%) | catalogued as COSV58419570; called by muse, mutect2, varscan2
- GALC | c.696C>A p.S232= | Silent (SNP) | VAF 132/677 reads (19%) | catalogued as COSV54328373; called by muse, mutect2, varscan2
- GLI2 | c.2340C>T p.T780= (on ENST00000361492 / NM_001374353.1; = p.T797= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/190 reads (21%) | called by muse, mutect2, varscan2
- GLYATL1 | c.618A>G p.P206= (on ENST00000317391 / NM_001354699.1; = p.P237= on NM_080661.4) | Silent (SNP) | VAF 141/1093 reads (13%) | called by muse, mutect2, varscan2
- GPC5 | c.891G>T p.R297= | Silent (SNP) | VAF 79/382 reads (21%) | called by muse, mutect2, varscan2
- GRID2IP | c.208C>A p.R70= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as rs544688737; called by muse, mutect2, varscan2
- H2AC4 | c.192G>T p.L64= | Silent (SNP) | VAF 170/565 reads (30%) | catalogued as COSV52517845; called by muse, mutect2, varscan2
- H4C2 | c.162G>A p.E54= | Silent (SNP) | VAF 296/815 reads (36%) | catalogued as rs147907725, COSV99774681; called by muse, mutect2, varscan2
- IGSF1 | c.1618A>C p.R540= | Silent (SNP) | VAF 149/339 reads (44%) | catalogued as COSV100811836; called by muse, mutect2, varscan2
- IGSF9 | c.2175G>T p.T725= (on ENST00000368094 / NM_001135050.2; = p.T709= on NM_020789.4) | Silent (SNP) | VAF 26/256 reads (10%) | called by muse, mutect2, varscan2
- IRS1 | c.2625A>G p.R875= | Silent (SNP) | VAF 231/561 reads (41%) | called by muse, varscan2
- LONRF2 | c.66G>A p.P22= | Silent (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1149T>A p.I383= | Silent (SNP) | VAF 100/525 reads (19%) | called by muse, mutect2, varscan2
- MED14 | c.1734T>C p.R578= | Silent (SNP) | VAF 133/304 reads (44%) | called by muse, mutect2, varscan2
- MEPE | c.981A>T p.A327= | Silent (SNP) | VAF 249/670 reads (37%) | called by muse, mutect2, varscan2
- MPV17L2 | c.9G>T p.R3= | Silent (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- NAP1L2 | c.600C>T p.D200= | Silent (SNP) | VAF 41/226 reads (18%) | catalogued as COSV100999239, COSV65172930; called by muse, mutect2, varscan2
- NLRC4 | c.924C>A p.L308= | Silent (SNP) | VAF 245/794 reads (31%) | called by muse, mutect2, varscan2
- NLRP4 | c.2640T>A p.G880= | Silent (SNP) | VAF 121/491 reads (25%) | called by muse, mutect2, varscan2
- NOS2 | c.2124C>T p.H708= | Silent (SNP) | VAF 167/639 reads (26%) | called by muse, mutect2, varscan2
- NRXN3 | c.1209C>A p.G403= (on ENST00000335750 / NM_001330195.2; = p.G30= on NM_004796.6) | Silent (SNP) | VAF 79/339 reads (23%) | catalogued as rs1398346818; called by muse, mutect2, varscan2
- OAF | c.591G>A p.E197= | Silent (SNP) | VAF 59/173 reads (34%) | called by muse, mutect2, varscan2
- OAS2 | c.432C>T p.A144= | Silent (SNP) | VAF 28/223 reads (13%) | catalogued as rs376806742; called by muse, mutect2, varscan2
- OR11G2 | c.750C>A p.L250= | Silent (SNP) | VAF 88/838 reads (11%) | catalogued as COSV62132805; called by muse, mutect2, varscan2
- OR2A2 | c.375C>T p.I125= | Silent (SNP) | VAF 33/413 reads (8%) | catalogued as rs1423959472; called by muse, mutect2
- OR2A25 | c.460T>C p.L154= | Silent (SNP) | VAF 285/980 reads (29%) | catalogued as rs372084976; called by muse, mutect2, varscan2
- OR2V1 | c.135C>T p.L45= | Silent (SNP) | VAF 209/761 reads (27%) | catalogued as rs1262255891; called by muse, mutect2, varscan2
- OR6B1 | c.402C>A p.T134= | Silent (SNP) | VAF 34/279 reads (12%) | catalogued as rs976289610; called by muse, mutect2, varscan2
- PID1 | c.351G>A p.E117= (on ENST00000354069 / NM_001330156.1; = p.E115= on NM_017933.5) | Silent (SNP) | VAF 162/398 reads (41%) | called by muse, mutect2, varscan2
- PLCH2 | c.1824C>T p.G608= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs1474212174; called by muse, mutect2, varscan2
- PPP1R26 | c.1413C>A p.S471= | Silent (SNP) | VAF 94/553 reads (17%) | called by muse, mutect2, varscan2
- PTK6 | c.1338C>T p.S446= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV53918808; called by muse, mutect2, varscan2
- PTPRB | c.5808G>A p.V1936= | Silent (SNP) | VAF 72/625 reads (12%) | called by muse, mutect2, varscan2
- PWWP2B | c.348G>A p.P116= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs755996285; called by muse, mutect2, varscan2
- REM2 | c.630A>G p.L210= | Silent (SNP) | VAF 202/795 reads (25%) | called by muse, mutect2, varscan2
- RETSAT | c.687T>G p.T229= | Silent (SNP) | VAF 286/1018 reads (28%) | called by muse, mutect2, varscan2
- ROBO4 | c.36G>A p.R12= | Silent (SNP) | VAF 71/285 reads (25%) | called by muse, varscan2
- RP1 | c.2316A>G p.G772= | Silent (SNP) | VAF 71/266 reads (27%) | called by muse, mutect2, varscan2
- RYR2 | c.9828T>C p.L3276= | Silent (SNP) | VAF 32/242 reads (13%) | called by muse, mutect2
- SHROOM4 | c.4245G>A p.T1415= | Silent (SNP) | VAF 49/231 reads (21%) | catalogued as rs1192413196; called by muse, mutect2, varscan2
- SI | c.1308C>A p.A436= | Silent (SNP) | VAF 157/1146 reads (14%) | catalogued as rs1033490058; called by muse, mutect2, varscan2
- SLC19A3 | c.846T>C p.S282= | Silent (SNP) | VAF 97/261 reads (37%) | called by muse, mutect2, varscan2
- SLC2A4 | c.1126C>A p.R376= | Silent (SNP) | VAF 218/727 reads (30%) | called by muse, mutect2, varscan2
- SLC39A12 | c.93C>A p.A31= | Silent (SNP) | VAF 184/882 reads (21%) | catalogued as COSV66202824; called by muse, mutect2, varscan2
- SMARCC1 | c.60G>T p.G20= | Silent (SNP) | VAF 101/257 reads (39%) | called by muse, mutect2, varscan2
- SNIP1 | c.267C>T p.S89= | Silent (SNP) | VAF 183/897 reads (20%) | called by muse, mutect2, varscan2
- TNPO2 | c.804G>A p.E268= | Silent (SNP) | VAF 70/313 reads (22%) | called by muse, mutect2, varscan2
- TRAF3IP2 | c.486C>G p.G162= | Silent (SNP) | VAF 95/1117 reads (9%) | called by muse, mutect2
- TRAV41 | c.45G>A p.Q15= | Silent (SNP) | VAF 176/575 reads (31%) | called by muse, mutect2, varscan2
- TRIM43B | c.408C>T p.D136= | Silent (SNP) | VAF 54/736 reads (7%) | called by muse, mutect2
- VPS13D | c.11433C>T p.T3811= | Silent (SNP) | VAF 76/788 reads (10%) | catalogued as rs751626556, COSV50622723, COSV99169144; called by muse, mutect2
- XIRP1 | c.597G>A p.P199= | Silent (SNP) | VAF 87/294 reads (30%) | catalogued as rs1448430613, COSV61137283; called by muse, mutect2, varscan2
- XKR3 | c.957C>T p.F319= | Silent (SNP) | VAF 50/488 reads (10%) | called by muse, mutect2, varscan2
- ZFHX4 | c.5175C>A p.T1725= | Silent (SNP) | VAF 123/760 reads (16%) | called by muse, mutect2, varscan2
- ZNF160 | c.696T>A p.S232= | Silent (SNP) | VAF 123/506 reads (24%) | called by muse, mutect2, varscan2
- ZNF473 | c.2205C>T p.C735= | Silent (SNP) | VAF 109/555 reads (20%) | catalogued as rs754078259; called by muse, mutect2, varscan2
- ACP1 | c.-14C>G | 5'UTR (SNP) | VAF 58/194 reads (30%) | called by muse, mutect2, varscan2
- ANK1 | c.5619+1313C>G | Intron (SNP) | VAF 125/433 reads (29%) | catalogued as COSV55892682; called by muse, mutect2, varscan2
- CACNA1G | c.*447T>C | 3'UTR (SNP) | VAF 86/1044 reads (8%) | called by muse, mutect2
- CCNJL | n.138T>A | RNA (SNP) | VAF 109/342 reads (32%) | called by muse, mutect2, varscan2
- CHTF18 | c.1105-24C>T | Intron (SNP) | VAF 22/176 reads (13%) | catalogued as rs371392899; called by muse, mutect2, varscan2
- COL4A3 | c.2747-23A>G | Intron (SNP) | VAF 155/448 reads (35%) | called by muse, mutect2, varscan2
- DHRS4 | c.722+13G>C | Intron (SNP) | VAF 111/477 reads (23%) | called by muse, mutect2, varscan2
- DNAH3 | c.118-4263T>A | Intron (SNP) | VAF 52/428 reads (12%) | called by muse, mutect2, varscan2
- EDA | c.397-96142G>C | Intron (SNP) | VAF 190/412 reads (46%) | called by muse, mutect2, varscan2
- FKBP9 | c.221+5796C>T | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- GLRXP3 | n.303G>T | RNA (SNP) | VAF 107/371 reads (29%) | called by muse, mutect2, varscan2
- GPC1 | c.167-6185C>T | Intron (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- HERC1 | c.12796+156C>T | Intron (SNP) | VAF 65/181 reads (36%) | catalogued as rs1288686550; called by muse, mutect2, varscan2
- HMG20B | c.941+102G>A | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- HYDIN | c.-134G>T | 5'UTR (SNP) | VAF 49/448 reads (11%) | called by muse, mutect2, varscan2
- ICAM1 | c.-23A>G | 5'UTR (SNP) | VAF 99/465 reads (21%) | called by muse, mutect2, varscan2
- ITPK1 | c.-62G>T | 5'UTR (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- ITPK1 | c.-63G>T | 5'UTR (SNP) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- KCNC3 | c.*1359del | 3'UTR (DEL) | VAF 24/128 reads (19%) | catalogued as rs760460194; called by mutect2, varscan2
- KIF1B | c.2115+6945A>G | Intron (SNP) | VAF 50/518 reads (10%) | called by muse, mutect2
- LAG3 | c.-7A>T | 5'UTR (SNP) | VAF 93/372 reads (25%) | called by muse, mutect2, varscan2
- LINC00452 | n.653C>T | RNA (SNP) | VAF 54/295 reads (18%) | called by muse, mutect2, varscan2
- MASP2 | c.412+37G>C | Intron (SNP) | VAF 75/256 reads (29%) | called by muse, mutect2, varscan2
- MTRR | c.56+19C>G | Intron (SNP) | VAF 235/1233 reads (19%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.769G>C | RNA (SNP) | VAF 95/797 reads (12%) | called by muse, mutect2, varscan2
- OR2M1P | n.630T>C | RNA (SNP) | VAF 232/1270 reads (18%) | called by muse, varscan2
- PNKD | c.236+1086G>A | Intron (SNP) | VAF 52/643 reads (8%) | catalogued as rs1245108087, COSV50308282; called by muse, mutect2
- POMT2 | c.438+24G>C | Intron (SNP) | VAF 130/1041 reads (12%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77918892 C>T | 5'Flank (SNP) | VAF 441/1306 reads (34%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159841 G>T | 5'Flank (SNP) | VAF 97/284 reads (34%) | called by muse, mutect2, varscan2
- RPL37A | c.-17A>T | 5'UTR (SNP) | VAF 72/440 reads (16%) | called by muse, mutect2, varscan2
- RPL3L | c.-46G>A | 5'UTR (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- SH3BP2 | c.239+428G>T | Intron (SNP) | VAF 93/426 reads (22%) | catalogued as rs758874555; called by muse, mutect2, varscan2
- SNORD116-7 | n.22T>A | RNA (SNP) | VAF 325/855 reads (38%) | called by muse, mutect2, varscan2
- SNORD116-9 | n.95C>A | RNA (SNP) | VAF 246/676 reads (36%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.838C>A | RNA (SNP) | VAF 220/1165 reads (19%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2287G>T | RNA (SNP) | VAF 351/1183 reads (30%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532542 C>A | 5'Flank (SNP) | VAF 75/552 reads (14%) | called by muse, mutect2, varscan2
- YAF2 | c.152+27013G>T | Intron (SNP) | VAF 74/324 reads (23%) | called by muse, mutect2, varscan2
- ZNF726 | c.4-27A>G | Intron (SNP) | VAF 194/744 reads (26%) | called by muse, mutect2, varscan2
